Somatic mutation profile of tumor specimen TCGA-AX-A06J-01A (aliquot TCGA-AX-A06J-01A-11W-A027-09) from TCGA case TCGA-AX-A06J, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 71.2 years (26,000 days).
Specimen TCGA-AX-A06J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87596375-d857-47cc-a2f5-0de1b3a2c136.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A06J-10A (Blood Derived Normal), aliquot TCGA-AX-A06J-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4137526-e8c9-4121-8393-e8a9f17482de

The open-access MAF lists 66 somatic variants for this specimen: 49 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 16, Frame Shift Del 4, Nonsense Mutation 1, In Frame Ins 1, Frame Shift Ins 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 109/141 reads (77%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1133G>T p.C378F | Missense Mutation (SNP) | VAF 94/135 reads (70%) | hotspot (GDC flag); SIFT tolerated (0.68); PolyPhen benign (0.019); catalogued as CM126691, COSV55930877, COSV55952006; called by muse, mutect2, varscan2
- SOX17 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52024163; called by muse, mutect2, varscan2
- ABHD17B | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as COSV100330279; called by muse, mutect2, varscan2
- ACSS2 | c.1727-1G>A p.X576_splice | Splice Site (SNP) | VAF 22/252 reads (9%) | catalogued as COSV99404582; called by muse, mutect2
- ADGRG4 | c.6172A>T p.T2058S | Missense Mutation (SNP) | VAF 173/488 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV99796460; called by muse, mutect2, varscan2
- ADGRV1 | c.13813G>A p.E4605K | Missense Mutation (SNP) | VAF 105/319 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.112); catalogued as rs770827231, COSV101316390; called by muse, mutect2, varscan2
- AKAP11 | c.2699T>G p.V900G | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV99214266; called by muse, mutect2, varscan2
- APOB | c.4430A>C p.Q1477P | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.826); catalogued as COSV99267451; called by muse, mutect2
- CDKL5 | c.2573G>A p.R858H | Missense Mutation (SNP) | VAF 162/432 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.959); catalogued as rs759083770, COSV101184440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL16A1 | c.2347G>A p.G783R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1176277321, COSV99595288; called by muse, mutect2
- CRYGA | c.68G>T p.C23F | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV100378602; called by muse, mutect2, varscan2
- EIF1AX | c.209G>C p.W70S | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100792184, COSV63309475; called by muse, mutect2, varscan2
- FAM117A | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778097783, COSV99544664, COSV99545120; called by muse, mutect2
- FAM47A | c.1493C>T p.T498I | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV100650033; called by muse, mutect2, varscan2
- GTSE1 | c.1678C>G p.P560A | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.041); catalogued as COSV101483229, COSV101483249; called by muse, mutect2, varscan2
- H1-4 | c.517C>G p.P173A | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.632); catalogued as COSV99175358; called by muse, varscan2
- H4C12 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.662); catalogued as rs772156373, COSV62743962; called by muse, mutect2, varscan2
- HDX | c.125A>T p.K42M | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52983223, COSV99947928, COSV99948040; called by muse, mutect2
- HJV | c.1153C>T p.R385* (on ENST00000336751 / NM_213653.4; = p.R272* on NM_145277.5) | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as rs782803011, CM041369, COSV100382379; called by muse, mutect2, varscan2
- KCNN2 | c.640A>G p.I214V (on ENST00000264773; = p.I426V on NM_021614.4) | Missense Mutation (SNP) | VAF 244/673 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.05); catalogued as rs199821673, COSV99300583; called by muse, mutect2, varscan2
- MGAT4C | c.1174dup p.I392Nfs*2 | Frame Shift Ins (INS) | VAF 18/85 reads (21%) | catalogued as rs746398787; called by mutect2, varscan2
- MYL10 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56207463, COSV99781156; called by muse, mutect2, varscan2
- NCAPD2 | c.3902A>G p.K1301R | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99975652; called by muse, mutect2, varscan2
- NIF3L1 | c.955A>T p.M319L (on ENST00000409020 / NM_001369444.1; = p.M292L on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.257); catalogued as COSV100677588; called by muse, mutect2
- OR4D5 | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 89/324 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV58306063, COSV58307098; called by muse, mutect2, varscan2
- PDE1A | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 90/256 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV100116071; called by muse, mutect2, varscan2
- PHLPP1 | c.3350T>C p.L1117P | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99409087; called by muse, mutect2, varscan2
- PTEN | c.83T>A p.I28N | Missense Mutation (SNP) | VAF 284/341 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100911169, COSV64296071, COSV64296742; called by muse, mutect2, varscan2
- SETD5 | c.2170C>T p.R724C | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56706996; called by muse, mutect2
- SGCE | c.250C>T p.R84W (on ENST00000647096; = p.R48W on NM_003919.3) | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs760964336, COSV56016049; called by muse, mutect2, varscan2
- SLC8A3 | c.2495T>G p.V832G (on ENST00000381269 / NM_183002.3; = p.V830G on NM_033262.4) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99385795; called by muse, mutect2, varscan2
- SLITRK5 | c.1791A>T p.K597N | Missense Mutation (SNP) | VAF 94/255 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV100281118; called by muse, mutect2, varscan2
- SMARCA5 | c.424C>G p.R142G | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV51648136, COSV99304128; called by muse, mutect2, varscan2
- STK31 | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100669856; called by muse, mutect2
- SVIL | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100880855, COSV100881289; called by muse, mutect2, varscan2
- TACSTD2 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs1454245377, COSV64667039; called by muse, varscan2
- TCEAL5 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 434/1350 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV101013176; called by muse, varscan2
- UBXN2A | c.337G>T p.V113F | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100465268; called by muse, mutect2, varscan2
- USH2A | c.86C>A p.S29Y | Missense Mutation (SNP) | VAF 89/231 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.365); catalogued as COSV100241225, COSV56397901; called by muse, mutect2, varscan2
- VWCE | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs926949322, COSV100076092; called by muse, mutect2, varscan2
- ZNF280B | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 147/682 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV64529786; called by muse, mutect2, varscan2
- ZNF99 | c.895C>T p.H299Y | Missense Mutation (SNP) | VAF 146/383 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.333); catalogued as rs1435274706, COSV101233930; called by muse, mutect2, varscan2
- ARID1A | c.3686_3689del p.N1229Rfs*7 | Frame Shift Del (DEL) | VAF 66/212 reads (31%) | called by mutect2, pindel, varscan2
- GJC3 | c.79_98del p.V27Cfs*13 | Frame Shift Del (DEL) | VAF 15/60 reads (25%) | called by mutect2, varscan2
- KNL1 | c.5737del p.R1913Dfs*11 (on ENST00000346991 / NM_170589.5; = p.R1887Dfs*11 on NM_144508.5) | Frame Shift Del (DEL) | VAF 18/129 reads (14%) | called by mutect2, pindel, varscan2
- MCF2L2 | c.1065_1079dup p.V356_L360dup | In Frame Ins (INS) | VAF 40/189 reads (21%) | called by mutect2, varscan2
- TEX13A | c.1012del p.A338Pfs*15 | Frame Shift Del (DEL) | VAF 56/199 reads (28%) | called by mutect2, pindel, varscan2
- AVPR1A | c.975G>T p.S325= | Silent (SNP) | VAF 10/157 reads (6%) | catalogued as COSV100146897; called by muse, mutect2
- DBR1 | c.342A>G p.K114= | Silent (SNP) | VAF 95/145 reads (66%) | catalogued as COSV99604608; called by muse, mutect2, varscan2
- INSL6 | c.249G>A p.P83= | Silent (SNP) | VAF 49/165 reads (30%) | catalogued as rs146054352, COSV67563407; called by muse, mutect2, varscan2
- MCM2 | c.2301C>T p.I767= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs575627406, COSV54034392; called by muse, mutect2, varscan2
- NLRP4 | c.2742G>A p.A914= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs772255842, COSV56720892; called by muse, mutect2, varscan2
- OR4K14 | c.762T>A p.P254= | Silent (SNP) | VAF 41/115 reads (36%) | catalogued as COSV100520512; called by muse, mutect2, varscan2
- RASD2 | c.426C>T p.N142= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs772031079, COSV53352203; called by muse, mutect2, varscan2
- ROBO4 | c.2496C>T p.S832= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs771809588, COSV100127812; called by muse, mutect2, varscan2
- SCN4A | c.4608C>T p.A1536= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs764476134, COSV71127433; ClinVar: likely benign; called by muse, mutect2, varscan2
- STAP2 | c.705G>A p.S235= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV99696991; called by muse, mutect2, varscan2
- SUSD4 | c.261C>T p.D87= | Silent (SNP) | VAF 50/151 reads (33%) | catalogued as rs149710544; called by muse, mutect2, varscan2
- SYMPK | c.1440G>A p.K480= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV55610383; called by muse, mutect2, varscan2
- TENM1 | c.5233C>T p.L1745= | Silent (SNP) | VAF 36/197 reads (18%) | catalogued as COSV100950716; called by muse, mutect2, varscan2
- TTN | c.70293T>A p.V23431= (on ENST00000591111; = p.V16007= on NM_003319.4) | Silent (SNP) | VAF 76/340 reads (22%) | catalogued as COSV100626632; called by muse, mutect2, varscan2
- UGT1A1 | c.21C>T p.G7= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs780253764, COSV100530873; called by muse, mutect2, varscan2
- ZP2 | c.1305C>T p.V435= | Silent (SNP) | VAF 70/204 reads (34%) | catalogued as rs768429680, COSV54813026; called by muse, mutect2, varscan2
- HERC2P3 | n.1556G>A | RNA (SNP) | VAF 22/71 reads (31%) | catalogued as rs774836694; called by muse, mutect2, varscan2
